Surgical pathology report (de-identified scan), TCGA case TCGA-99-8032, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Alabama, specimen TCGA-99-8032-01A (Primary Tumor).

[page 1 of 2]
Patient Name	MR#	Observation Date	Last Edited Date

SURGICAL PATHOLOGY

CASE:

Received Date:

Diagnosis

A. Lymph node, level VIII, excision:

- Benign fibroadipose tissue with no significant histopathological abnormalities. - No lymph nodes noted.

B. Lymph node, level IX, excision:- One lymph node negative for malignancy (0/1).

C. Lymph node, level VII, excision: - Multiple lymph nodes negative for malignancy.

D. Lymph nodes, level II, excision: - Multiple lymph nodes negative for malignancy.

E. Lymph nodes, level IV-R, excision:- Multiple lymph nodes negative for malignancy.

F. Lymph node, level XI, excision: - One lymph negative for malignancy (0/1).

G. Bronchial margin, excision: - Negative for malignancy.

H. Lung, right upper lobe, lobectomy: - Adenocarcinoma, moderately differentiated. - Tumor measures 2.0 cm in maximal dimension. - Pleura is not involved by tumor. - Surgical resection margin is free of tumor. - Multiple peribronchial lymph nodes negative for malignancy. - Subpleural bullae noted.

(Electronically signed by) Verified:

Clinical Information

The patient is a year old male with lung nodule.

Frozen Section Diagnosis

GFS1 - Bronchial margin, biopsy:- No tumor seen.

HFS1 - Lung, right upper lobe, excision: - Non small cell carcinoma, consistent with adenocarcinoma.

Gross Description

The specimen are received in eight separate containers, each labeled with the patient's name and medical record number. The first container is further labeled "#1 level VIII lymph node". It consist of small pieces of lymphoid tissue that measure 0.5 x 0.3 x 0.2 cm in three dimension. This material will be submitted entirely.

The second container is further labeled "#2 level IX lymph node". It consist of lymph nodes that measure 0.7 x 0.5 x 0.4 cm in three dimension. This material will be submitted entirely.

The third container is further labeled "#3 level VII lymph node". It consist of a piece of tan-pink, soft tissue with lymph nodes that measure 2.5 x 1.6 x 0.3 cm in three dimension. The specimen will be submitted entirely.

The fourth container is further labeled "#4 level II lymph node". It consist of multiple pieces of tan and yellow, soft tissue with lymph nodes that measure 2.2 x 1.5 x 0.6 cm in aggregate. The lymph node will be dissected from soft tissue and will be submitted entirely.

The fifth container is further labeled "#5 level IV-R lymph node". It consist of multiple pieces of tan and yellow, soft tissue with lymph nodes that measure 2.4 x 1.3 x 0.8 cm in aggregate. The lymph node will be dissected from the tissue and will be submitted entirely.

The sixth container is further labeled "#6 level XI lymph node". It consist of small pieces of lymph node that measure 0.4 x 0.3 x 0.3 cm in three dimensions. The specimen will be submitted entirely.

[page 2 of 2]
The seventh container is further labeled "#7 bronchial margin". It consist of a cassette that is labeled "G1, [REDACTED]", that contain material for previous frozen analysis. The specimen measure 0.9 x 0.4 x 0.3 cm in three dimension. This material will be submitted in cassette G1.

The eighth container is further labeled "#8 right upper lobe". It consist of a cassette that is labeled "H1, [REDACTED]". The cassette contain the material for previous frozen analysis that measure 2.1 x 1.2 x 0.3 cm in three dimension. This specimen will be resubmitted in cassette H1. The specimen measure 13.5 x 10.1 x 2.5 cm in three dimension. There is a tumor nodule lesion identified that measure 2.0 cm in maximal dimension. The cut surface of the lesion is tan-white with focal black area. The lesion is located about 4.5 cm away from the nearest surgical resection margin. There is a second lesion identified that measure 4.5 cm in maximum dimension. This is a cyst-like lesion. Serial sections reveal solid lesion with firm and solid component. The second lesion is located about 1.0 cm away from the first lesion. Serial section through the rest of the lung tissue reveal no other apparent lesions. A representative section will be submitted per block summary. [REDACTED]

Block Summary

- A1 - Level VIII lymph node
- B1 - Level IX lymph node
- C1 - Level VII lymph node
- D1 - Level II lymph node
- E1 - Level IV-R lymph node
- F1 - Level XI lymph node
- G1 - Bronchial margin-frozen section
- H1 - Right upper lobe-frozen section
- H2 - Peribronchial lymph nodes
- H3 - Parenchymal surgical resection margin close to the tumor
- H4 - Bronchial surgical margin
- H5 - Blood vessel surgical margin
- H6-H9-Solid nodular lung lesion
- H10 - Cystic lung lesion

Microscopic Description: A microscopic examination has been performed. [REDACTED]

SP Synoptic Report H: Thorax Lung

SPECIMEN: Lobe(s) of lung: Right upper lobe

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Upper lobe

TUMOR SIZE: Greatest dimension: 2.0 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

VASCULAR MARGIN: Uninvolved by invasive carcinoma

PARENCHYMAL MARGIN: Uninvolved by invasive carcinoma

PARIETAL PLEURAL MARGIN: Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: LYMPH NODES: Not identified

PRIMARY TUMOR (pT): pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

Source: NCI Genomic Data Commons file 1d3d20fa-0d9a-46cb-93dc-86142277c98b (TCGA-99-8032.376597EF-E750-4F66-B744-2B042C0DF836.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).